Somatic mutation profile of tumor specimen TCGA-FY-A3BL-01A (aliquot TCGA-FY-A3BL-01A-11D-A19J-08) from TCGA case TCGA-FY-A3BL, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 29.2 years (10,667 days).
Specimen TCGA-FY-A3BL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86d3406b-bd2e-4c10-8623-cc1020cf4609.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A3BL-10A (Blood Derived Normal), aliquot TCGA-FY-A3BL-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4567ddfb-20de-4e38-85b7-4f438a219fb2

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- C12orf66 | c.151T>C p.W51R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61325073; called by muse, mutect2
- KMT2A | c.9182A>G p.N3061S | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.015); catalogued as rs782494435, COSV63282112; called by muse, mutect2, varscan2
- RXFP1 | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57057773; called by muse, mutect2, varscan2
- ZW10 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52320051; called by muse, mutect2, varscan2
- TBCC | c.9C>T p.S3= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as rs537953279, COSV55130640; called by mutect2, varscan2
